Somatic mutation profile of tumor specimen MP2PRT-PATYAW-TMP1-A (aliquot MP2PRT-PATYAW-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PATYAW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,127 days).
Specimen MP2PRT-PATYAW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90c43f40-6604-4ef5-aa50-fe2b742a0af3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATYAW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATYAW-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26c476c3-cb01-4389-8a1f-26743170c503

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACE2 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.277); catalogued as rs200540199, COSV53025304; called by muse, mutect2
- SIRPD | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 50/483 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs552135708, COSV67546697; called by muse, mutect2
- CLK2 | c.1038T>G p.H346Q (on ENST00000368361 / NM_001294339.2; = p.H345Q on NM_003993.4) | Missense Mutation (SNP) | VAF 123/394 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NXPH2 | c.236A>G p.N79S | Missense Mutation (SNP) | VAF 196/500 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.018); called by muse, mutect2
- TYK2 | c.3067G>C p.D1023H | Missense Mutation (SNP) | VAF 26/548 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDK5RAP2 | c.561G>A p.T187= | Silent (SNP) | VAF 122/345 reads (35%) | catalogued as rs756635555; called by muse, mutect2, varscan2
- TRPC3 | c.450G>A p.A150= (on ENST00000379645 / NM_001366479.2; = p.A77= on NM_003305.2) | Silent (SNP) | VAF 32/550 reads (6%) | catalogued as COSV53378884; called by muse, mutect2
- VAMP8 | c.162+609_162+610insGGTTCC | Intron (INS) | VAF 74/307 reads (24%) | called by mutect2, pindel, varscan2
